Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8DF, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8DF-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report
* Procedure/Addenda present *

ICD-O3
Thymoma, type AB, malignant 8082/3
Site: Thymus C37.9
path
Mediastinum, anterior C38.1
QW 6/13/14

Taken: DOB: Gender: M

Operative Procedure:
Sternotomy, mediastinal mass resection

Pre-Operative Diagnosis:
As below

Post-Operative Diagnosis:
As below

Specimen Received:
A: Anterior mediastinal mass
B: AP window lymph node

Addendum Report

Addendum Diagnosis

A representative portion of this case is sent for specialized laboratory testing. This addendum is created to report that the results are scanned into the patient's electronic medical record

TEST/ASSAY

RESULTS

Thymoma Class = 1

Patients with a Class1 molecular signature have a low risk of experiencing near term (within 10 years) clinical metastasis.

Addendum Comment

A section or paraffin block from the patient's thymoma tissue was sent for
Thymoma(tm) Gene Expression Assay

Type of Specimen: FFPE prepared tumor tissue

THYMOMA GENE EXPRESSION ASSAY DESCRIPTION

THYMOMA<174> gene expression assay for thymoma tumors is a proprietary

[page 2 of 3]
assay which uses RT-PCR to determine the expression levels of a 23 gene panel (4 controls) in primary tumor tissue samples. THYMOMA<174>
classification is calculated from the gene expression results as compared to results of a training set of patients with known outcomes.

Final Pathologic Diagnosis:

A. Thymus, anterior mediastinal mass, excision:

Thymoma, type AB.

See Synoptic Report and Note below.

Synoptic Report

Specimen:	Anterior mediastinal mass
Procedure:	Mediastinal mass resection
Specimen integrity:	Intact
Specimen weight:	135 grams
Tumor size:	4.4 cm (greatest dimension)
Histologic type:	Thymoma, type AB
Tumor extension:	Invades into capsule without transcapsular invasion
Margins:	Margins uninvolved by tumor Distance of tumor from closest margin: less than 1 mm
Treatment effect:	Not applicable
Lymph-vascular invasion:	Present within the capsule
Regional lymph nodes:	
Number examined:	1 (AP window part B)
Number involved:	0

Pathologic staging for thymomas: Stage I

Implants/distant metastasis: Cannot be assessed

Additional pathologic findings: None

B. Lymph node, AP window, excision:

One lymph node, without significant pathologic change (0/1).

See Synoptic Report and Note below.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Received are two formalin filled containers labeled with the patient's name.

Part A is additionally labeled "anterior mediastinal mass" and consists of a portion of yellow-tan fatty tissue weighing 135 grams with overall dimensions of 12.2 x 8.1 x 3.6 cm. The external surface of the specimen is yellow-tan and lobular with a single patch of attached mesothelium with dimensions of 6.0 x 3.1

[page 3 of 3]
cm. The external surface is inked black. The specimen has been previously incised and a portion of this tissue has been banked with the Tissue Bank. Sectioning through the specimen reveals a single well-encapsulated mass with dimensions of 4.2 x 3.2 x 4.4 cm. The cut surface of the mass is white-tan, somewhat lobular, and fleshy. The capsule of the mass abuts the inked external surface. The capsule surrounding the mass is partially calcified. The remaining fatty tissue has a yellow-tan, lobular cut surface with no additional masses identified. Representative sections of the mass are submitted in cassettes A1-6.

Part B is additionally labeled "AP window lymph node" and consists of a single black-tan, rubbery lymph node with dimensions of 1.0 x 0.8 x 0.7 cm. The specimen is trisected and entirely submitted in cassette B1.

Microscopic Description:
The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Source: NCI Genomic Data Commons file 7fbf4100-3f2d-4306-9a84-528f771e9957 (TCGA-X7-A8DF.8DDC446F-FBC4-4394-AD6C-2E60D9AA3240.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).